CCDI case PBCVVF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/290c1ad3-517b-4b1c-b4db-9c8f3dc0c347

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1SBV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1SC0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1SCG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
